Gene-level copy-number profile of tumor specimen C3L-00157-02 from CPTAC case C3L-00157, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.6 years (22,118 days).
Specimen C3L-00157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 044d4e7f-62a0-4857-b0df-80872ba094d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00157-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/c70c6b71-e25b-4690-a9bb-6adcedf6fc53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 64; copy number 2: 8,423; copy number 3: 17,264; copy number 4: 20,725; copy number 5: 8,521; copy number 6: 817; copy number 7: 1,159; copy number 8: 332; copy number 9: 259; copy number 10: 140; copy number 11: 353; copy number 12: 17; copy number 13: 5; copy number 14: 8; copy number 15: 63; copy number 17: 169; copy number 19: 1; copy number 22: 10; copy number 27: 44; copy number 28: 25.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,094 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,756,199–149,051,273, 54 genes, copy number 9: GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1.
- chr1:240,636,599–241,357,230, 11 genes, copy number 9 (within-gene range 8–9): AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1.
- chr2:38,814–20,401,724, 294 genes, copy number 9–11 (broad region; genes not listed).
- chr9:130,902,438–131,820,988, 24 genes, copy number 9: FIBCD1, AL161733.1, LAMC3, AL583807.1, AIF1L, NUP214, RNU6-881P, AL157938.2, AL157938.3, AL157938.1, FAM78A, PLPP7, PRRC2B, SNORD62A, SNORD62B, AL358781.1, POMT1, AL358781.2, UCK1, RAPGEF1, RN7SL328P, EIF4A1P3, AL160271.1, AL160271.2.
- chr10:120,925,547–121,133,723, 3 genes, copy number 13: AC010998.1, AC010998.3, RPL19P16.
- chr11:102,107,886–102,628,070, 17 genes, copy number 12: AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.
- chr12:55,954,105–56,113,910, 14 genes, copy number 11: PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4.
- chr17:31,759,795–32,491,253, 41 genes, copy number 11: GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,509,954–32,531,492, 5 genes, copy number 11 (within-gene range 8–11): AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.
- chr17:37,798,894–37,884,743, 2 genes, copy number 13: AC243571.1, YWHAEP7.
- chr17:39,603,536–39,730,426, 8 genes, copy number 14 (within-gene range 8–14): NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2.
- chr17:41,688,885–41,865,423, 12 genes, copy number 10: EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11.
- chr17:49,202,791–50,236,129, 54 genes, copy number 11: GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7.
- chr17:58,353,676–58,557,799, 6 genes, copy number 10 (within-gene range 2–10): RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4.
- chr18:45,034–4,455,307, 98 genes, copy number 15–17 (within-gene range 7–17) (broad region; genes not listed).
- chr18:30,713,275–48,863,217, 231 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:48,826,051–49,048,474, 5 genes, copy number 11 (within-gene range 2–11): AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1.
- chr19:27,681,072–30,228,715, 56 genes, copy number 15–28 (within-gene range 5–28): LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr19:30,907,199–31,655,461, 12 genes, copy number 15–22: LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471.
- chr19:36,054,881–38,587,564, 103 genes, copy number 17 (within-gene range 6–17) (broad region; genes not listed).
- chr19:39,328,353–39,981,764, 43 genes, copy number 27: GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4.
- chr20:47,391,925–47,412,327, 1 gene, copy number 11: LINC01754.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
